Somatic mutation profile of tumor specimen C3N-08032-01 (aliquot CPT0470970006) from CPTAC case C3N-08032, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 62.2 years (22,710 days).
Specimen C3N-08032-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 716210b0-e636-4dff-adb6-17066e3643ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-08032-31 (Blood Derived Normal), aliquot CPT0471030006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa385335-ce0e-45c4-86c6-b45370e19321

The open-access MAF lists 273 somatic variants for this specimen: 168 protein-altering or splice-affecting, 88 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 88, Nonsense Mutation 16, Intron 8, 5'UTR 3, RNA 2, Frame Shift Del 2, 3'UTR 2, Splice Region 1, 5'Flank 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 242/416 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNGB3 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 53/158 reads (34%) | catalogued as rs764742792, CM050554, COSV60684823; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD31 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV57157349; called by muse, mutect2, varscan2
- ATAD2 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 121/255 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1404857864, COSV54880665; called by muse, mutect2, varscan2
- BAZ1A | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 187/399 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs775846470; called by muse, mutect2, varscan2
- BCO1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 207/247 reads (84%) | SIFT tolerated (0.45); PolyPhen benign (0.438); catalogued as rs763897086; called by muse, mutect2, varscan2
- BTBD11 | c.2920C>T p.Q974* (on ENST00000280758 / NM_001018072.2; = p.Q511* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 101/261 reads (39%) | catalogued as rs267603283, COSV55039078; called by muse, mutect2, varscan2
- C8orf58 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 195/262 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.421); catalogued as rs1309027656; called by muse, mutect2, varscan2
- CCDC88C | c.4153G>A p.E1385K | Missense Mutation (SNP) | VAF 127/322 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66236472; called by muse, mutect2, varscan2
- CCDC9B | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 173/460 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749781667; called by muse, mutect2, varscan2
- CDH20 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 166/447 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs753375305, COSV53019864; called by muse, mutect2, varscan2
- CFAP65 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 162/387 reads (42%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV55389509; called by muse, mutect2, varscan2
- CNTN2 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 179/399 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765367852, COSV59352562; called by muse, mutect2, varscan2
- COL19A1 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308868390; called by muse, mutect2, varscan2
- COL19A1 | c.2746C>T p.P916S | Missense Mutation (SNP) | VAF 175/396 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100505704, COSV59566794; called by muse, mutect2, varscan2
- COL5A1 | c.4051G>A p.G1351R | Missense Mutation (SNP) | VAF 151/370 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190522168, COSV65670068; called by muse, mutect2, varscan2
- CPM | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 128/344 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs755183423, COSV104405381, COSV58031716; called by muse, mutect2, varscan2
- CSMD1 | c.2341G>A p.D781N (on ENST00000520002; = p.D780N on NM_033225.6) | Missense Mutation (SNP) | VAF 132/187 reads (71%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.81); catalogued as COSV100153372; called by muse, mutect2, varscan2
- CSMD2 | c.9665C>T p.S3222F | Missense Mutation (SNP) | VAF 216/459 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1283339217; called by muse, mutect2, varscan2
- CXXC1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 163/416 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs773971072, COSV53273402; called by muse, mutect2, varscan2
- DCAF8L1 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 188/214 reads (88%) | SIFT tolerated (0.3); PolyPhen benign (0.155); catalogued as rs1310904525, COSV71595267; called by muse, mutect2, varscan2
- DSC2 | c.2359G>A p.V787M | Missense Mutation (SNP) | VAF 178/404 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.259); catalogued as rs1789053; called by muse, mutect2, varscan2
- EDAR | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 190/408 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as rs761615482, COSV51501437; called by muse, mutect2, varscan2
- ERICH3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 171/213 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs746026874, COSV58604107; called by muse, mutect2, varscan2
- FAM81B | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 126/341 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV51982079; called by muse, mutect2, varscan2
- FGF6 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57403569; called by muse, mutect2
- GALNT10 | c.828C>G p.Y276* | Nonsense Mutation (SNP) | VAF 187/416 reads (45%) | catalogued as rs770121388, COSV51732623, COSV51733628; called by muse, mutect2, varscan2
- HAO1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs866463468, COSV66491681; called by muse, mutect2, varscan2
- IGHV7-81 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 140/300 reads (47%) | catalogued as rs1364475623; called by muse, mutect2
- IRAG1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 128/456 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1183222150; called by muse, mutect2, varscan2
- KAAG1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 196/472 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); catalogued as COSV99219734; called by muse, varscan2
- KCNG4 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 255/336 reads (76%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as rs868649320; called by muse, mutect2, varscan2
- KIF5A | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 138/322 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1224640834; called by muse, mutect2, varscan2
- KRT73 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 116/333 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.297); catalogued as COSV59838510; called by muse, mutect2, varscan2
- LMO7 | c.502A>T p.N168Y (on ENST00000357063; = p.N183Y on NM_005358.5) | Missense Mutation (SNP) | VAF 151/332 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV58552257; called by muse, mutect2, varscan2
- LPIN2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 163/369 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV55236867; called by muse, mutect2, varscan2
- LRP1B | c.10747G>A p.D3583N | Missense Mutation (SNP) | VAF 129/323 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752198878, COSV67249373; called by muse, mutect2, varscan2
- LRP1B | c.8713C>T p.P2905S | Missense Mutation (SNP) | VAF 169/416 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs751149662, COSV67197305; called by muse, mutect2, varscan2
- MGA | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 207/478 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs752397560, COSV54950393, COSV54956965; called by muse, mutect2, varscan2
- MGAM | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 160/530 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1163875284, COSV72073816; called by muse, mutect2, varscan2
- MISP | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 201/489 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs1253103491; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 132/324 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV100186804; called by muse, mutect2, varscan2
- MRGPRX2 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 485/809 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.395); catalogued as rs141744602; called by muse, mutect2, varscan2
- MUC16 | c.17876C>T p.S5959F | Missense Mutation (SNP) | VAF 176/383 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV67448919; called by muse, mutect2, varscan2
- MUC19 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 175/406 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1460838437; called by muse, mutect2
- MUC5AC | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 115/442 reads (26%) | SIFT deleterious (0); catalogued as COSV62255022; called by muse, mutect2, varscan2
- MYLK | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 128/162 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60608109; called by muse, mutect2, varscan2
- NAV3 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 175/220 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57080007; called by muse, mutect2, varscan2
- NPSR1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 243/433 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs568145224, COSV62202336; called by muse, mutect2, varscan2
- NWD1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 137/331 reads (41%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.467); catalogued as COSV60337354; called by muse, mutect2, varscan2
- OGFOD3 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 107/291 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs761016972; called by muse, mutect2, varscan2
- OR13C2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 116/350 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220001507, COSV73377667; called by muse, mutect2, varscan2
- OR2G6 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 193/410 reads (47%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs138211669; called by muse, mutect2, varscan2
- OR5D18 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 170/361 reads (47%) | catalogued as COSV61738360; called by muse, mutect2, varscan2
- OTX2 | c.608C>T p.S203L (on ENST00000408990 / NM_172337.3; = p.S211L on NM_021728.4) | Missense Mutation (SNP) | VAF 192/494 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV59767727; called by muse, mutect2
- PANX2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 305/349 reads (87%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.996); catalogued as COSV99348139; called by muse, mutect2, varscan2
- PAOX | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 180/228 reads (79%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99529970; called by muse, mutect2, varscan2
- PCDHA4 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 208/520 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs567779090, COSV63543453; called by muse, mutect2, varscan2
- PLCL1 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 228/531 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as rs45596936; called by muse, mutect2, varscan2
- PLEKHG7 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 126/320 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs1179483150, COSV60822792; called by muse, mutect2, varscan2
- POLRMT | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 238/549 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs751661059; called by muse, mutect2, varscan2
- POM121L12 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 212/814 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.798); catalogued as rs746175412, COSV68692799; called by muse, mutect2, varscan2
- PPP2R5D | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 169/443 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1024917557; called by muse, mutect2, varscan2
- PRLR | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 197/441 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs865855838, COSV51497549; called by muse, mutect2, varscan2
- PSD4 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 168/428 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as rs201640002; called by muse, mutect2, varscan2
- RIMBP2 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 203/461 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55469901; called by muse, mutect2, varscan2
- RPS6KA6 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 138/176 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV53124656; called by muse, mutect2, varscan2
- RRH | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 344/579 reads (59%) | catalogued as rs1167769599; called by muse, mutect2, varscan2
- RUNX1T1 | c.1548G>A p.W516* (on ENST00000265814 / NM_001198628.1; = p.W489* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 116/308 reads (38%) | catalogued as COSV56139090; called by muse, mutect2, varscan2
- SULT1E1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 136/254 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.072); catalogued as rs766053586; called by muse, mutect2
- SYNE1 | c.20593C>T p.Q6865* (on ENST00000367255 / NM_182961.4; = p.Q6794* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 364/585 reads (62%) | catalogued as COSV54906575; called by muse, mutect2, varscan2
- SYNE1 | c.13208C>T p.S4403L (on ENST00000367255 / NM_182961.4; = p.S4332L on NM_033071.3) | Missense Mutation (SNP) | VAF 161/569 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs139490297; called by muse, mutect2, varscan2
- THSD7B | c.3340G>A p.E1114K (on ENST00000272643; = p.E1112K on NM_001316349.2) | Missense Mutation (SNP) | VAF 194/452 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV55652012; called by muse, mutect2, varscan2
- TLR3 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 125/362 reads (35%) | catalogued as rs780744847, COSV99710784; called by muse, mutect2, varscan2
- TMPRSS11F | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 92/306 reads (30%) | catalogued as rs542655796, COSV62464715; called by muse, mutect2, varscan2
- TSHR | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 199/489 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1374886905, COSV53324296; called by muse, mutect2, varscan2
- WDR87 | c.5399G>A p.R1800Q | Missense Mutation (SNP) | VAF 198/444 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376310584; called by muse, mutect2, varscan2
- WDR87 | c.4241G>A p.G1414E | Missense Mutation (SNP) | VAF 197/423 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0.083); catalogued as COSV58193729; called by muse, mutect2, varscan2
- XIRP2 | c.496C>T p.H166Y (on ENST00000628543; = p.H341Y on NM_152381.6) | Missense Mutation (SNP) | VAF 156/338 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.418); catalogued as COSV54728150, COSV54741680; called by muse, mutect2, varscan2
- ZBTB49 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 136/479 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs1265588413; called by muse, mutect2, varscan2
- ZNF638 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 163/206 reads (79%) | SIFT tolerated (0.17); PolyPhen benign (0.194); catalogued as COSV100040227; called by muse, mutect2, varscan2
- ZSCAN18 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 201/471 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as rs1386866534; called by muse, mutect2, varscan2
- ADAMTS7 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 183/426 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANKRD36 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ANKRD60 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 213/446 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANO2 | c.1498C>T p.Q500* (on ENST00000356134 / NM_001278597.3; = p.Q504* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 122/339 reads (36%) | called by muse, mutect2, varscan2
- AOC2 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 196/434 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AP002748.5 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 227/573 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- APOB | c.12665G>A p.R4222K | Missense Mutation (SNP) | VAF 183/365 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- APOBR | c.1813C>T p.P605S (on ENST00000431282; = p.P614S on NM_018690.4) | Missense Mutation (SNP) | VAF 202/461 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ARHGEF4 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 224/568 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- ATP6V0C | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 236/550 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- BICDL1 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 210/532 reads (39%) | called by muse, mutect2, varscan2
- C4B | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by mutect2, varscan2
- CCDC18 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 104/135 reads (77%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC7 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC9B | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 169/456 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CD180 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 173/391 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH15 | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 216/273 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CDH15 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 213/271 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- CDH18 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CELA2B | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 160/205 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP70 | c.2950G>A p.A984T | Missense Mutation (SNP) | VAF 219/273 reads (80%) | SIFT tolerated (0.19); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CLEC4C | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 138/412 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- CORO2A | c.734G>A p.W245* | Nonsense Mutation (SNP) | VAF 170/393 reads (43%) | called by muse, mutect2, varscan2
- CRYBG1 | c.5389G>A p.D1797N | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBG2 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 160/348 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CSPG4 | c.3230C>T p.P1077L | Missense Mutation (SNP) | VAF 152/392 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CUX2 | c.66G>A p.K22= | Splice Region (SNP) | VAF 72/167 reads (43%) | called by muse, mutect2, varscan2
- CUX2 | c.2440G>A p.G814S | Missense Mutation (SNP) | VAF 229/568 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- DDX3X | c.1507G>A p.G503R (on ENST00000399959; = p.G504R on NM_001356.5) | Missense Mutation (SNP) | VAF 122/142 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- DGKI | c.1553G>A p.G518D | Missense Mutation (SNP) | VAF 237/374 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- DHX33 | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 228/274 reads (83%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by muse, varscan2
- EPHA1 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 309/523 reads (59%) | called by muse, mutect2, varscan2
- F2 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 129/340 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- F5 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 185/389 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.13457C>T p.P4486L | Missense Mutation (SNP) | VAF 378/433 reads (87%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FOXI3 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 213/297 reads (72%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- FRMPD4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/306 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- G3BP1 | c.1301del p.P434Lfs*9 | Frame Shift Del (DEL) | VAF 194/558 reads (35%) | called by pindel, varscan2
- GC | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 375/590 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GJA9 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 152/352 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRC6A | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 119/289 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HBG2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 340/826 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ISM2 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ITGA7 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 172/411 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- KCNJ6 | c.46T>A p.S16T | Missense Mutation (SNP) | VAF 164/325 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LRP2 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MAGEA12 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 181/207 reads (87%) | SIFT tolerated (0.08); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MCM3 | c.656C>T p.P219L (on ENST00000229854 / NM_001366374.2; = p.P209L on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 178/397 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAA16 | c.1060A>T p.K354* | Nonsense Mutation (SNP) | VAF 100/259 reads (39%) | called by muse, mutect2, varscan2
- NCKAP5L | c.3350C>T p.S1117F | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEBL | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 120/280 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NME1-NME2 | c.623T>C p.M208T (on ENST00000555572; = p.M183T on NM_001018136.3) | Missense Mutation (SNP) | VAF 154/340 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR5H8 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 119/159 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PALMD | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 118/137 reads (86%) | SIFT tolerated (0.57); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PEAK1 | c.4187C>A p.A1396D | Missense Mutation (SNP) | VAF 187/421 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PEAK1 | c.4186G>A p.A1396T | Missense Mutation (SNP) | VAF 185/425 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLA1A | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 176/217 reads (81%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PRPS1L1 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 176/571 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSG6 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PSTPIP1 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 154/365 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTPN13 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 143/534 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- REELD1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 224/254 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- RYR2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 148/371 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SAV1 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 108/268 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SETDB1 | c.2360G>C p.C787S | Missense Mutation (SNP) | VAF 153/323 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLFN14 | c.2570G>A p.G857E | Missense Mutation (SNP) | VAF 193/518 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SNTN | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 119/260 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- SSU72P5 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 169/930 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SYNJ1 | c.744T>G p.C248W | Missense Mutation (SNP) | VAF 141/359 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCP11X2 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TENM2 | c.7238G>A p.G2413E (on ENST00000518659 / NM_001122679.2; = p.G2174E on NM_001080428.3) | Missense Mutation (SNP) | VAF 214/430 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TEP1 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 209/448 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TESPA1 | c.1274C>T p.P425L (on ENST00000316577 / NM_001098815.3; = p.P287L on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 193/419 reads (46%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TM9SF2 | c.1678_1700del p.L560Yfs*4 | Frame Shift Del (DEL) | VAF 38/268 reads (14%) | called by mutect2, pindel, varscan2
- TMEM101 | c.755T>G p.I252S | Missense Mutation (SNP) | VAF 133/305 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- TMEM40 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 107/259 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TPH1 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 227/375 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TTN | c.5242G>A p.A1748T (on ENST00000591111; = p.A1702T on NM_003319.4) | Missense Mutation (SNP) | VAF 215/516 reads (42%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VARS1 | c.3748C>T p.L1250F | Missense Mutation (SNP) | VAF 211/523 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- WBP11 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 206/461 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY4 | c.9388G>A p.E3130K | Missense Mutation (SNP) | VAF 102/128 reads (80%) | SIFT tolerated (0.09); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- WDR81 | c.4648C>T p.P1550S (on ENST00000409644 / NM_001163809.2; = p.P499S on NM_152348.4) | Missense Mutation (SNP) | VAF 259/338 reads (77%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBED2 | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 192/232 reads (83%) | called by muse, varscan2
- ZBTB49 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 136/481 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZNF100 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 159/362 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF385B | c.118A>G p.S40G | Missense Mutation (SNP) | VAF 222/502 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCB1 | c.3186G>A p.K1062= | Silent (SNP) | VAF 211/662 reads (32%) | catalogued as COSV99713661; called by muse, mutect2, varscan2
- ACR | c.1233C>T p.T411= | Silent (SNP) | VAF 60/140 reads (43%) | called by muse, mutect2, varscan2
- ADGRG7 | c.1173G>A p.K391= | Silent (SNP) | VAF 167/210 reads (80%) | called by muse, mutect2, varscan2
- ALPK1 | c.3375G>A p.K1125= | Silent (SNP) | VAF 158/521 reads (30%) | called by muse, mutect2, varscan2
- ATRN | c.3909C>T p.I1303= | Silent (SNP) | VAF 166/407 reads (41%) | called by muse, mutect2, varscan2
- BICD2 | c.1002C>T p.S334= | Silent (SNP) | VAF 133/306 reads (43%) | catalogued as rs1403546969; called by muse, mutect2, varscan2
- BICDL1 | c.282C>T p.S94= | Silent (SNP) | VAF 210/534 reads (39%) | catalogued as rs749881243; called by muse, mutect2, varscan2
- C2 | c.828C>T p.S276= | Silent (SNP) | VAF 296/717 reads (41%) | catalogued as rs747305157; called by muse, mutect2, varscan2
- C3 | c.3330G>A p.E1110= | Silent (SNP) | VAF 146/344 reads (42%) | called by muse, mutect2, varscan2
- C3orf22 | c.159G>A p.T53= | Silent (SNP) | VAF 178/216 reads (82%) | catalogued as rs1267424764; called by muse, mutect2, varscan2
- C8orf58 | c.411C>T p.S137= | Silent (SNP) | VAF 193/260 reads (74%) | called by muse, mutect2, varscan2
- CC2D1A | c.1794C>T p.T598= | Silent (SNP) | VAF 100/257 reads (39%) | catalogued as COSV58785831; called by muse, mutect2, varscan2
- CD14 | c.840C>T p.S280= | Silent (SNP) | VAF 163/397 reads (41%) | called by muse, mutect2, varscan2
- CIDEA | c.111C>T p.F37= | Silent (SNP) | VAF 197/463 reads (43%) | catalogued as rs374372121; called by muse, mutect2, varscan2
- CLN3 | c.1227C>T p.F409= (on ENST00000360019 / NM_001286104.2; = p.F433= on NM_000086.2) | Silent (SNP) | VAF 128/257 reads (50%) | catalogued as rs1479016838; called by muse, mutect2, varscan2
- CNTN2 | c.1326C>T p.P442= | Silent (SNP) | VAF 182/402 reads (45%) | called by muse, mutect2, varscan2
- CPNE5 | c.597C>T p.P199= | Silent (SNP) | VAF 116/281 reads (41%) | catalogued as COSV55200403; called by muse, mutect2, varscan2
- CRNKL1 | c.279G>A p.K93= | Silent (SNP) | VAF 189/469 reads (40%) | catalogued as rs1441231867, COSV99846804; called by muse, mutect2, varscan2
- CRYBG1 | c.5388G>A p.E1796= | Silent (SNP) | VAF 87/261 reads (33%) | called by muse, mutect2, varscan2
- CTLA4 | c.516G>A p.S172= | Silent (SNP) | VAF 170/385 reads (44%) | catalogued as rs375949600; called by muse, mutect2, varscan2
- DNAH17 | c.1500G>A p.L500= | Silent (SNP) | VAF 147/355 reads (41%) | catalogued as rs754988436; called by muse, mutect2, varscan2
- DNAH7 | c.9633C>T p.S3211= | Silent (SNP) | VAF 194/428 reads (45%) | catalogued as COSV100417685; called by muse, mutect2, varscan2
- DYSF | c.4671C>T p.D1557= | Silent (SNP) | VAF 165/222 reads (74%) | called by muse, mutect2, varscan2
- EPHB2 | c.582C>T p.Y194= | Silent (SNP) | VAF 225/507 reads (44%) | called by muse, mutect2, varscan2
- FCGR2B | c.351G>A p.Q117= | Silent (SNP) | VAF 135/555 reads (24%) | called by muse, mutect2, varscan2
- FER1L5 | c.3657G>A p.K1219= (on ENST00000623019; = p.K1192= on NM_001293083.2) | Silent (SNP) | VAF 175/415 reads (42%) | called by muse, mutect2, varscan2
- FOXO3 | c.1971G>A p.G657= | Silent (SNP) | VAF 112/269 reads (42%) | catalogued as rs1044115208, COSV59630716; called by muse, mutect2, varscan2
- GALNT14 | c.1602C>T p.V534= | Silent (SNP) | VAF 179/226 reads (79%) | catalogued as rs1274769856, COSV61102602; called by muse, mutect2, varscan2
- GNA15 | c.858C>T p.I286= | Silent (SNP) | VAF 179/429 reads (42%) | catalogued as rs748435713, COSV53586227; called by muse, mutect2
- GUCY2D | c.102C>T p.P34= | Silent (SNP) | VAF 239/307 reads (78%) | catalogued as rs1262337868, COSV54699321; called by muse, mutect2, varscan2
- HAL | c.1620G>A p.R540= | Silent (SNP) | VAF 167/410 reads (41%) | called by muse, mutect2, varscan2
- HMCN1 | c.16002C>T p.P5334= | Silent (SNP) | VAF 154/347 reads (44%) | catalogued as rs373461955, COSV54917926; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ISM2 | c.600C>T p.T200= | Silent (SNP) | VAF 102/234 reads (44%) | called by muse, mutect2, varscan2
- KCNA5 | c.525C>T p.I175= | Silent (SNP) | VAF 245/561 reads (44%) | catalogued as rs527435500, COSV99363711; called by muse, mutect2, varscan2
- KCNJ4 | c.858C>T p.I286= | Silent (SNP) | VAF 396/458 reads (86%) | catalogued as rs757723128, COSV57857452; called by muse, mutect2, varscan2
- L3MBTL4 | c.1791T>A p.I597= | Silent (SNP) | VAF 210/489 reads (43%) | called by muse, mutect2
- LKAAEAR1 | c.492C>T p.P164= | Silent (SNP) | VAF 193/476 reads (41%) | called by muse, mutect2, varscan2
- LRP2 | c.3381C>T p.V1127= | Silent (SNP) | VAF 171/393 reads (44%) | called by muse, mutect2, varscan2
- LRRC41 | c.816C>T p.G272= | Silent (SNP) | VAF 207/491 reads (42%) | called by muse, mutect2, varscan2
- LRRC69 | c.849C>T p.I283= | Silent (SNP) | VAF 202/442 reads (46%) | catalogued as COSV100645697; called by muse, varscan2
- LRRN3 | c.915G>A p.V305= | Silent (SNP) | VAF 316/536 reads (59%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.822C>T p.F274= | Silent (SNP) | VAF 361/633 reads (57%) | catalogued as rs866353263, COSV57105708; called by muse, mutect2, varscan2
- MUC4 | c.3402C>T p.A1134= | Silent (SNP) | VAF 174/652 reads (27%) | called by muse, varscan2
- MUC5AC | c.1230C>T p.S410= | Silent (SNP) | VAF 115/440 reads (26%) | catalogued as rs1330893079, COSV62253315; called by muse, mutect2, varscan2
- MYH8 | c.2388G>A p.R796= | Silent (SNP) | VAF 158/204 reads (77%) | called by muse, mutect2, varscan2
- MYPOP | c.786C>T p.F262= | Silent (SNP) | VAF 192/474 reads (41%) | catalogued as rs1203659185; called by muse, mutect2
- NEU4 | c.195C>T p.S65= (on ENST00000391969 / NM_001167602.3; = p.S77= on NM_080741.4) | Silent (SNP) | VAF 182/453 reads (40%) | catalogued as rs202101402; called by muse, mutect2, varscan2
- NLRP4 | c.435G>A p.G145= | Silent (SNP) | VAF 182/476 reads (38%) | catalogued as rs775033164; called by muse, mutect2
- OR10G9 | c.672C>T p.I224= | Silent (SNP) | VAF 180/228 reads (79%) | catalogued as rs1011409931; called by muse, mutect2, varscan2
- OR1N1 | c.861C>T p.I287= | Silent (SNP) | VAF 174/411 reads (42%) | catalogued as COSV59195059; called by muse, mutect2, varscan2
- OR2F2 | c.771C>T p.F257= | Silent (SNP) | VAF 357/569 reads (63%) | catalogued as COSV101283798; called by muse, mutect2, varscan2
- OR52N2 | c.903G>A p.Q301= | Silent (SNP) | VAF 284/512 reads (55%) | catalogued as COSV57677275; called by muse, mutect2, varscan2
- OR5B3 | c.96C>T p.I32= | Silent (SNP) | VAF 165/403 reads (41%) | called by muse, mutect2, varscan2
- PANX2 | c.507C>T p.A169= | Silent (SNP) | VAF 309/352 reads (88%) | catalogued as rs1280308056; called by muse, mutect2, varscan2
- PDZD7 | c.747G>A p.E249= | Silent (SNP) | VAF 143/189 reads (76%) | catalogued as rs754062325; called by muse, mutect2, varscan2
- PLA1A | c.321C>T p.T107= | Silent (SNP) | VAF 172/212 reads (81%) | called by muse, mutect2, varscan2
- PLEC | c.13572C>T p.F4524= (on ENST00000322810 / NM_201380.4; = p.F4414= on NM_000445.5) | Silent (SNP) | VAF 226/548 reads (41%) | catalogued as COSV59625414; called by muse, mutect2, varscan2
- PLXNA4 | c.2721T>C p.G907= | Silent (SNP) | VAF 290/474 reads (61%) | called by muse, mutect2, varscan2
- PPP2R3B | c.771C>T p.F257= | Silent (SNP) | VAF 226/677 reads (33%) | called by muse, mutect2, varscan2
- PPP4R4 | c.2280G>A p.S760= | Silent (SNP) | VAF 170/382 reads (45%) | catalogued as rs367998986; called by muse, mutect2, varscan2
- PRAMEF14 | c.660G>A p.L220= | Silent (SNP) | VAF 219/296 reads (74%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.490C>T p.L164= | Silent (SNP) | VAF 173/234 reads (74%) | catalogued as rs768301704; called by muse, mutect2, varscan2
- PTPN13 | c.1107C>T p.P369= | Silent (SNP) | VAF 143/537 reads (27%) | called by muse, mutect2, varscan2
- PTPRT | c.453C>T p.L151= | Silent (SNP) | VAF 194/428 reads (45%) | catalogued as rs140340339, COSV61962190, COSV61991072, COSV62009332; called by muse, mutect2, varscan2
- RET | c.1269G>A p.G423= | Silent (SNP) | VAF 92/131 reads (70%) | called by muse, mutect2, varscan2
- RP1L1 | c.5496C>T p.A1832= | Silent (SNP) | VAF 241/308 reads (78%) | catalogued as rs369137346; called by muse, mutect2, varscan2
- RPS6KA6 | c.741G>A p.R247= | Silent (SNP) | VAF 137/176 reads (78%) | called by muse, mutect2, varscan2
- SCN11A | c.1884C>T p.I628= | Silent (SNP) | VAF 168/407 reads (41%) | catalogued as rs866427407, COSV56565994, COSV56580456; called by muse, mutect2, varscan2
- SDAD1 | c.570G>A p.R190= | Silent (SNP) | VAF 110/354 reads (31%) | catalogued as rs778917596; called by muse, mutect2, varscan2
- SLC15A3 | c.1701C>T p.S567= | Silent (SNP) | VAF 182/431 reads (42%) | called by muse, mutect2, varscan2
- SLC22A5 | c.555C>T p.F185= | Silent (SNP) | VAF 207/469 reads (44%) | called by muse, mutect2, varscan2
- SLC2A1 | c.1134C>T p.F378= | Silent (SNP) | VAF 163/387 reads (42%) | catalogued as rs758184335; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC6A7 | c.342C>T p.L114= | Silent (SNP) | VAF 110/216 reads (51%) | called by muse, mutect2, varscan2
- SLITRK5 | c.858G>A p.R286= | Silent (SNP) | VAF 185/392 reads (47%) | called by muse, mutect2, varscan2
- SPTA1 | c.2433G>A p.E811= | Silent (SNP) | VAF 126/341 reads (37%) | catalogued as COSV100935613; called by muse, mutect2, varscan2
- SRGAP3 | c.609C>T p.L203= | Silent (SNP) | VAF 191/428 reads (45%) | catalogued as rs916860965, COSV64532347; called by muse, mutect2, varscan2
- SYNDIG1 | c.429C>T p.I143= | Silent (SNP) | VAF 159/389 reads (41%) | called by muse, mutect2, varscan2
- TRBV6-1 | c.190C>T p.L64= | Silent (SNP) | VAF 150/498 reads (30%) | called by muse, varscan2
- TRPC7 | c.1644C>T p.V548= | Silent (SNP) | VAF 195/459 reads (42%) | catalogued as rs1238116647, COSV100725646; called by muse, mutect2, varscan2
- TRRAP | c.10203C>T p.A3401= (on ENST00000359863 / NM_001244580.1; = p.A3372= on NM_003496.3) | Silent (SNP) | VAF 198/646 reads (31%) | catalogued as rs769399893; called by muse, mutect2, varscan2
- UNC13A | c.2151G>A p.G717= | Silent (SNP) | VAF 147/333 reads (44%) | called by muse, mutect2, varscan2
- UVSSA | c.735C>T p.P245= | Silent (SNP) | VAF 492/838 reads (59%) | catalogued as COSV101104538; called by muse, mutect2, varscan2
- VEZT | c.160C>T p.L54= | Silent (SNP) | VAF 121/234 reads (52%) | called by muse, mutect2, varscan2
- XRCC4 | c.294G>A p.E98= | Silent (SNP) | VAF 100/257 reads (39%) | called by muse, mutect2, varscan2
- ZCCHC12 | c.1143C>T p.T381= | Silent (SNP) | VAF 233/262 reads (89%) | catalogued as COSV100038516; called by muse, mutect2, varscan2
- ZNF267 | c.2091C>T p.F697= | Silent (SNP) | VAF 214/522 reads (41%) | catalogued as rs1228516014; called by muse, mutect2, varscan2
- ZNF687 | c.3285G>A p.P1095= | Silent (SNP) | VAF 41/597 reads (7%) | catalogued as rs749845698, COSV55016437; called by muse, mutect2
- ZYG11A | c.1347C>T p.L449= | Silent (SNP) | VAF 86/222 reads (39%) | called by muse, mutect2, varscan2
- AC004922.1 | c.*204G>A | 3'UTR (SNP) | VAF 288/526 reads (55%) | called by muse, mutect2, varscan2
- AC004922.1 | c.*205G>A | 3'UTR (SNP) | VAF 287/523 reads (55%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.725G>A | RNA (SNP) | VAF 143/366 reads (39%) | catalogued as rs1553559491, COSV71422767; called by muse, mutect2, varscan2
- ARHGAP28 | c.2030+1850G>A | Intron (SNP) | VAF 105/325 reads (32%) | catalogued as COSV51633421; called by muse, mutect2, varscan2
- FARP1 | c.-1C>T | 5'UTR (SNP) | VAF 104/282 reads (37%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640410 G>A | 3'Flank (SNP) | VAF 124/156 reads (79%) | called by muse, mutect2, varscan2
- MGAM | c.4618+3206C>T | Intron (SNP) | VAF 270/499 reads (54%) | catalogued as COSV101527417; called by muse, mutect2, varscan2
- PRSS3 | c.-295G>T | 5'UTR (SNP) | VAF 336/400 reads (84%) | catalogued as rs1383884217; called by muse, mutect2, varscan2
- RGS5 | c.45-4197A>G | Intron (SNP) | VAF 141/322 reads (44%) | called by muse, mutect2, varscan2
- RIMS1 | c.1679-20582G>A | Intron (SNP) | VAF 119/307 reads (39%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22613431 C>T | 5'Flank (SNP) | VAF 17/99 reads (17%) | catalogued as rs942709368; called by mutect2, varscan2
- RUBCNL | c.-122-5335C>T | Intron (SNP) | VAF 111/263 reads (42%) | called by muse, mutect2, varscan2
- SETDB1 | c.1140+46G>A | Intron (SNP) | VAF 107/263 reads (41%) | catalogued as rs776843147; called by muse, mutect2, varscan2
- SPATA8 | n.848G>A | RNA (SNP) | VAF 147/286 reads (51%) | catalogued as rs145348357, COSV60704703; called by muse, mutect2, varscan2
- SRPX2 | c.-1G>A | 5'UTR (SNP) | VAF 157/172 reads (91%) | called by muse, mutect2, varscan2
- TMEM144 | c.109+26C>T | Intron (SNP) | VAF 60/213 reads (28%) | catalogued as rs748751547; called by muse, mutect2, varscan2
- TTN | c.10360+4648G>A | Intron (SNP) | VAF 162/381 reads (43%) | catalogued as COSV60378548; called by muse, mutect2, varscan2
